Somatic mutation profile of tumor specimen 0DC6NV from CCDI case PBBMFY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,082 days).
Specimen 0DC6NV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6c0a588-85af-47c9-b2e2-5d25d1a55d84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC6O2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fc7041b-84b5-4012-b240-0f6186eb24c0

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD6 | c.3176C>T p.S1059L | Missense Mutation (SNP) | VAF 495/2173 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV58557570, COSV58563525; called by muse, mutect2, varscan2
- COL28A1 | c.950C>A p.P317Q | Missense Mutation (SNP) | VAF 220/949 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as rs1319185978; called by muse, mutect2, varscan2
- CTSC | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 421/1936 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV57059437; called by muse, mutect2, varscan2
- HEMGN | c.186dup p.R63Tfs*47 | Frame Shift Ins (INS) | VAF 154/954 reads (16%) | catalogued as rs750485705; called by mutect2, varscan2
- KARS1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 74/1488 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV100093892; called by muse, mutect2
- PANK2 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 20/639 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PCOLCE2 | c.566A>C p.K189T | Missense Mutation (SNP) | VAF 222/696 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- POLR2A | c.3283C>T p.L1095F | Missense Mutation (SNP) | VAF 289/628 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- WNK1 | c.4978C>T p.R1660W (on ENST00000315939 / NM_018979.4; = p.R1413W on NM_014823.3) | Missense Mutation (SNP) | VAF 204/846 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMP1 | c.1233C>T p.H411= | Silent (SNP) | VAF 211/726 reads (29%) | catalogued as rs367740277; called by muse, mutect2, varscan2
- NOTCH2 | c.3555G>A p.E1185= | Silent (SNP) | VAF 61/1362 reads (4%) | catalogued as rs781999568; called by muse, mutect2
- PITPNM2 | c.2013C>T p.Y671= | Silent (SNP) | VAF 110/641 reads (17%) | catalogued as rs370272498, COSV99759155; called by muse, mutect2, varscan2
- TCHH | c.2748G>A p.E916= | Silent (SNP) | VAF 31/1191 reads (3%) | catalogued as rs1211355820; called by muse, mutect2
- MRNIP | chr5:179858826 G>A | 5'Flank (SNP) | VAF 33/141 reads (23%) | catalogued as rs906338240; called by muse, mutect2, varscan2
- TLN2 | c.*92C>T | 3'UTR (SNP) | VAF 51/101 reads (50%) | catalogued as rs1017031871; called by muse, mutect2, varscan2
